Surgical pathology report (de-identified scan), TCGA case TCGA-77-8130, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-8130-01A (Primary Tumor).

[page 1 of 2]
Collected [REDACTED]

Histopathology Report

LEFT UPPER LOBECTOMY AND HILAR LYMPH NODES

Clinical Details:
None supplied.

Two specimens submitted:

1: LEFT UPPER LOBE

Macroscopy:

The specimen consists of a lobectomy specimen weighing 419 g in the fixed state and measuring 170 x 115 x 65 mm. The pleural surface is mostly smooth, however there is an area of roughening on the lower medial surface measuring approximately 25 x 20 mm. In addition, adjacent to the hilum, there is a small piece of adherent pleura measuring 30 x 20 mm. On sectioning there is a large tumour present centrally within the lobe measuring 45 x 35 x 35 mm. This lesion invades the main lobar bronchus and extends to within approximately 11 mm of the bronchial resection margin. The resection margin does appear clear of tumour. The bronchus is almost completely occluded by tumour and distal bronchi show marked mucus plugging. Tumour appears to abut the medial pleural surface in several areas. There does not appear to be tumour extending through the pleural surface. Elsewhere the lung parenchyma shows anthracosis and emphysema, the latter of which is more prominent towards the apices. The lingula is markedly congested. No further mass lesions are noted. Macroscopically tumour appears to involve at least some of the peribronchial lymph nodes. [Sections taken through bronchial resection margins, A-B; parabronchial lymph node bisected, C; tumour invading bronchus, D-F (E and F represent a single slice bisected); tumour with overlying pleural surface, G-I; tumour and adjacent lung, J; random section from apex, K; and lingula, L].

Microscopy:

Sections show a poorly differentiated squamous cell carcinoma arising from a large bronchus and directly invading the adjacent pulmonary artery. This vessel is largely occluded, and numerous smaller branches distal to the main vessel are also obliterated by tumour. The tumour itself shows very extensive central necrosis. Tumour directly invades peribronchial lymph nodes. There is also invasion of pleura on the medial aspect of the lung. The bronchial resection margin is clear of malignancy but shows extensive squamous metaplasia and mild dysplasia. No lymphatic, venous or perineural infiltration is identified. Lung parenchyma distal to the tumour is confirmed to show bronchiectasis and mucus plugging. There is also emphysema but there is no evidence of active inflammation. Tissue from the lingula shows focal infarction.

Conclusion:

[page 2 of 2]
Collected [REDACTED]

Histopathology Report

Left upper lobectomy: Poorly differentiated squamous cell carcinoma, 45 mm in maximum diameter, invading pleura and pulmonary artery; pathological stage T2 N1.

2: HILAR LYMPH NODES

Macroscopy:

The specimen consists of multiple fragments of dark tan tissue measuring in aggregate 30 x 25 x 3 mm. [The majority of the tissue is BIT, 2A]. [REDACTED]

Microscopy:

Sections show multiple fragments of lymph node in which there are reactive changes but no evidence of metastatic squamous cell carcinoma.

Conclusion:

Hilar lymph nodes: No evidence of malignancy.

[REDACTED]

Copies:

Lung Cancer Registry

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 3a145dac-ff7f-454c-9d20-612987069c6a (TCGA-77-8130.B070100C-D021-4D9F-B665-441BFC3DF5B4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).